Somatic mutation profile of tumor specimen TARGET-20-PATCPY-04A (aliquot TARGET-20-PATCPY-04A-01D) from TARGET case TARGET-20-PATCPY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.2 years (6,659 days).
Specimen TARGET-20-PATCPY-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75c61796-34f9-4894-82bd-55427117a339.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATCPY-14A (Bone Marrow Normal), aliquot TARGET-20-PATCPY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71fd50e7-c9d7-4d7d-b7b7-464b420a95de

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: In Frame Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ILF3 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752415076; called by muse, mutect2, varscan2
- MYC | c.181_182insCCA p.L61delinsPM (on ENST00000377970; = p.L76delinsPM on NM_002467.6) | In Frame Ins (INS) | VAF 12/43 reads (28%) | called by mutect2, varscan2
